Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4853, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4853-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Accession Number: [REDACTED] Report Status: Amend/Addenda
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provide [REDACTED]

CASE: [REDACTED]

PATIENT: [REDACTED]

PATHOLOGIC DIAGNOSIS:

SPECIMEN LABELED "R KIDNEY":

RENAL CELL CARCINOMA, clear cell type (3.5 cm),

Fuhrman nuclear grade II/IV.

Ureteral margin is free of tumor.

Tumor is within 0.1 cm of the inked capsule margin (multiple levels examined).

No lymphovascular invasion is identified.

AJCC Classification (6th Edition): T1a Nx MX.

CLINICAL DATA:

History: Renal cell CA, R kidney.

Operation: Radical nephrectomy R.

Operative Findings: None given.

Clinical Diagnosis: None given.

TISSUE SUBMITTED:

#1 (P.S.) R kidney.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "Right kidney", and consists of a kidney (513 gm), measuring 24 x 8.5 x 4.8 cm overall. The kidney proper measures 10.8 x 5.0 x 5.0 cm. No adrenal gland is identified. A ureter (8 cm in length x 0.2 cm in diameter) and a renal vein (1.2 cm in length x 0.5 cm in diameter) are identified. However, renal artery is not seen. The external surface of the kidney is inked black. A soft, lobulated, tan tumor (3.5 x 2.5 x 2.5 cm) is identified in the lower pole, compressing the pelvis and abutting the capsule. The tumor does not invade the fat or the renal vein. Representative sections of tumor and normal are submitted for electromicroscopy and to Tissue Bank. Representative sections of the tumor are submitted to Cytogenetics, and normal tissue is submitted for IF. The remainder of the renal parenchyma is unremarkable.

Micro A1: Ureteral and renal vein margins, 2 frags, [REDACTED]
Micro A2: Tumor relative to pelvis, 1 frag, [REDACTED]
Micro A3: Tumor relative to normal parenchyma, 1 frag, [REDACTED]
Micro A4: Tumor relative to deep margin, 1 frag, [REDACTED]
Micro A5: Satellite tumor, 1 frag, [REDACTED]
Micro A6: Uninvolved renal parenchyma, 1 frag, [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Resident Review by [REDACTED]
Final Diagnosis by [REDACTED]

Electronically signed on [REDACTED]

ADDENDUM

RENAL PATHOLOGY EVALUATION OF NON-NEOPLASTIC KIDNEY PARENCHYMA [REDACTED]

[page 2 of 3]
Pathology Report

ARTERIAL AND ARTERIOLAR SCLEROSIS, MODERATE, WITH FOCAL GLOBAL
GLOMERULOSCLEROSIS (13.1% OF GLOMERULI; SEE NOTE).

NOTE:

The non-neoplastic renal parenchyma shows a significant degree of global glomerulosclerosis and moderate degree of vascular sclerosis. The preserved glomeruli are hypertrophic, an expected compensation for the obsolescence of numerous nephrons. Glomerulosclerosis is frequently the final consequence of adaptations that are brought about by hemodynamic changes and glomerular hypertrophy following loss of functioning nephrons. Such loss of nephrons is often the result of an independent primary glomerular, tubulo-Interstitial, or vascular disease, the latter being the most likely precipitant in this patient given the significant vascular scarring observed. These patients usually show only focal visceral epithelial cell foot process effacement ultrastructurally, and they may be at risk for persistent sub-nephrotic proteinuria; typically this is not associated with hypoalbuminemia or edema.

MICROSCOPIC DESCRIPTION:

The section for light microscopy contains cortex and medulla, and was evaluated using HE, PAS, Jones silver methenamine, and trichrome (AFOG) stains. There are a total of 275 glomeruli, thirty-six of which are globally obsolescent (sclerosed). Rare glomeruli appear segmentally sclerosed, and a majority of the preserved glomeruli are hypertrophic. There is minimal mesangial expansion of preserved glomeruli without discernible capillary wall or basement membrane changes. Tubules contain occasional PAS-positive casts, and there is no significant interstitial inflammation apart from scattered microscopic subcapsular scars. Approximately 10% of the sample shows tubular atrophy with about 30% interstitial fibrosis.

[page 3 of 3]
Pathology Report

Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist [REDACTED]

Report Status: Final

KARYOTYPE: See below

METAPHASES COUNTED: 0

ANALYZED: 0

SCORED: 0

BANDING: GTG

INTERPRETATION:

No metaphases were available from this specimen, therefore the cytogenetic analysis could not be performed.

INDICATION FOR TEST:

? RCC

Source: NCI Genomic Data Commons file 202847c0-2031-46d7-b77d-ae93e80b4cd2 (TCGA-CZ-4853.DA1086BF-1AB4-446A-B69D-13748884C522.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).